Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7882, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7882-01A (Primary Tumor).

Tumor Sample: [REDACTED]

Normal Sample: [REDACTED]

Microscopic Description:

Sections demonstrate an anaplastic glioma. The tumor cells demonstrate round to oval nuclei with coarse chromatin and irregular nuclear contours. In areas, the tumor cells demonstrate clear cytoplasm with a distinctly “fried egg” appearance. Fifteen mitoses are counted per ten high power fields. Hemorrhage and necrosis are observed. Focal areas of microvascular proliferation are observed. The tumor diffusely invades the surrounding brain.

Diagnosis:

Anaplastic Oligodendroglioma (WHO grade III)

Source: NCI Genomic Data Commons file 4dbf8b1e-e83c-4846-8c29-845d50477806 (TCGA-HT-7882.6EF48BA9-CDEB-4279-BD24-9DC228671262.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).